CPTAC case C3N-00249 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5bc6682f-914a-477d-9977-4b82d0e67183

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Dead; Days to death: 1,590 days (4.4 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Age at diagnosis: 71.5 years (26,108 days); Year of diagnosis: 2016; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,590 days (4.4 years); Progression or recurrence: yes; Days to last follow up: 1,590 days (4.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.2 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 25; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 375 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 717 days (2.0 years); Disease response: Progressive Disease.
- Days to follow up: 1,098 days (3.0 years); Disease response: Progressive Disease.
- Days to follow up: 1,425 days (3.9 years); Disease response: Progressive Disease.
- Days to follow up: 1,590 days (4.4 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 579 days (1.6 years).

Other clinical attributes
- Weight: 75.75 kg; Height: 165.1 cm; BMI: 27.79.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2; Cigarettes per day: 20; Tobacco smoking onset year: 1966; Tobacco smoking quit year: 1968; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 2.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00249-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 94 mg.
- Sample C3N-00249-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 74 mg.
- Sample C3N-00249-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 19 days; Initial weight: 282 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00249-23: Section location: Body; Percent tumor nuclei: 20; Percent necrosis: 1.
- Sample C3N-00249-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 19 days; Initial weight: 147 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00249-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 705 mg.
- Sample C3N-00249-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 19 days; Method of sample procurement: Blood Draw.
- Sample C3N-00249-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
